Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7857, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7857-01A (Primary Tumor).

**PATH REPORT****Microscopic**

Sections demonstrate a moderately hypercellular glial neoplasm. The tumor is composed of generally moderately atypical fibrillary astrocytes. In addition, many bizarre, multinucleated cells are seen. Neither microvascular proliferation nor tumor necrosis is present. Only a rare mitotic figure is seen. Which is unexpected given the degree of atypia. Nevertheless, the cytologic features are unequivocally anaplastic. No eosinophilic granular bodies or Rosenthal fibers are seen. There is no microcystic degeneration.

Addendum

Scattered MIB-1 cells are seen throughout the tumor. In the areas of highest proliferative activity, a labeling index of 6.5% is calculated. This is indicative of a moderately proliferative neoplasm that is consistent with the anaplastic cytologic features.

Diagnosis

Anaplastic astrocytoma Grade III

Source: NCI Genomic Data Commons file a26a572a-fc86-41c6-adcf-29c102630e1c (TCGA-HT-7857.3779C43D-34B9-426A-A59E-9E2379DC2634.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).